Somatic mutation profile of tumor specimen 0DL1TU from CCDI case PBBYUD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Nasopharynx, NOS; Age at diagnosis: 8.9 years (3,242 days).
Specimen 0DL1TU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39818e16-b181-495c-bff5-a35224a6c8c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DL1T0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f9352fd-9b07-4d2b-9bd2-3eab26294795

The open-access MAF lists 46 somatic variants for this specimen: 26 protein-altering or splice-affecting, 10 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 10, Intron 5, 3'UTR 3, Splice Region 2, Frame Shift Del 2, 5'UTR 1, Nonsense Mutation 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 154/220 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ADGRG3 | c.832G>T p.V278F | Missense Mutation (SNP) | VAF 96/273 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs754606663; called by muse, varscan2
- CYRIB | c.766G>A p.V256I | Missense Mutation (SNP) | VAF 108/812 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1445642879; called by muse, varscan2
- DMRTA1 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 87/202 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100364945; called by muse, varscan2
- GOLGA8M | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 86/732 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as rs1165818256; called by muse, varscan2
- HDX | c.1682C>G p.P561R | Missense Mutation (SNP) | VAF 74/102 reads (73%) | SIFT tolerated (0.63); PolyPhen benign (0.038); catalogued as COSV52974085, COSV99947724; called by muse, varscan2
- KRTAP9-3 | c.416G>C p.C139S | Missense Mutation (SNP) | VAF 128/528 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.426); catalogued as COSV68616627; called by muse, varscan2
- MAVS | c.1492G>A p.D498N | Missense Mutation (SNP) | VAF 114/356 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.028); catalogued as rs201947681; called by muse, varscan2
- PCDHA8 | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 122/369 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as rs553667841; called by muse, varscan2
- USP2 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 98/363 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.061); catalogued as rs376129505; called by muse, varscan2
- ABCA5 | c.589C>A p.L197M | Missense Mutation (SNP) | VAF 200/404 reads (50%) | SIFT tolerated (1); PolyPhen probably damaging (0.912); called by muse, varscan2
- AMER1 | c.1670_1671del p.E557Gfs*22 | Frame Shift Del (DEL) | VAF 96/267 reads (36%) | called by pindel, varscan2
- CACNB4 | c.390+7G>T | Splice Region (SNP) | VAF 127/240 reads (53%) | called by muse, varscan2
- CYP19A1 | c.725A>G p.K242R | Missense Mutation (SNP) | VAF 126/494 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, varscan2
- GOLGA6L2 | c.578A>G p.K193R | Missense Mutation (SNP) | VAF 62/235 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.696); called by muse, varscan2
- HNRNPD | c.1000+4_1000+7del | Splice Region (DEL) | VAF 68/226 reads (30%) | called by pindel, varscan2
- PCDHB4 | c.489C>G p.S163R | Missense Mutation (SNP) | VAF 154/508 reads (30%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.05); called by muse, varscan2
- PIEZO2 | c.7178G>A p.G2393D | Missense Mutation (SNP) | VAF 88/221 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- PLOD1 | c.1562G>T p.W521L | Missense Mutation (SNP) | VAF 191/444 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- RRP12 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 188/496 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.033); called by muse, varscan2
- SF3A1 | c.2086_2088del p.E696del | In Frame Del (DEL) | VAF 188/486 reads (39%) | called by pindel, varscan2
- SURF6 | c.822_823del p.Y275Qfs*9 | Frame Shift Del (DEL) | VAF 102/512 reads (20%) | called by pindel, varscan2
- THAP9 | c.1550T>C p.L517P | Missense Mutation (SNP) | VAF 166/477 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, varscan2
- TP53BP2 | c.422C>A p.A141E (on ENST00000343537 / NM_001031685.3; = p.A12E on NM_005426.2) | Missense Mutation (SNP) | VAF 95/251 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- VWDE | c.1372G>A p.D458N | Missense Mutation (SNP) | VAF 152/420 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.943); called by muse, varscan2
- ZBTB11 | c.3052C>T p.Q1018* | Nonsense Mutation (SNP) | VAF 120/339 reads (35%) | called by muse, varscan2
- CYB5RL | c.567G>A p.A189= | Silent (SNP) | VAF 131/329 reads (40%) | catalogued as rs757751724; called by muse, varscan2
- KCNQ1 | c.276C>T p.S92= | Silent (SNP) | VAF 162/807 reads (20%) | catalogued as rs1186599274; called by muse, varscan2
- MFSD12 | c.546C>T p.Y182= | Silent (SNP) | VAF 175/410 reads (43%) | catalogued as rs543321039; called by muse, varscan2
- MIP | c.42C>T p.F14= | Silent (SNP) | VAF 104/434 reads (24%) | catalogued as rs150017493; called by muse, varscan2
- PIEZO2 | c.7179C>A p.G2393= | Silent (SNP) | VAF 87/222 reads (39%) | called by muse, varscan2
- POP1 | c.567G>A p.T189= | Silent (SNP) | VAF 160/1132 reads (14%) | catalogued as rs781451136, COSV100855685; called by muse, varscan2
- REPS2 | c.1392C>T p.S464= | Silent (SNP) | VAF 166/231 reads (72%) | called by muse, varscan2
- SEMA4A | c.1179G>A p.K393= | Silent (SNP) | VAF 234/572 reads (41%) | called by muse, varscan2
- SPATA16 | c.1158T>G p.L386= | Silent (SNP) | VAF 120/452 reads (27%) | called by muse, varscan2
- UVSSA | c.1344G>A p.T448= | Silent (SNP) | VAF 144/420 reads (34%) | catalogued as rs750959163; called by muse, varscan2
- ARHGAP21 | c.*61_*62del | 3'UTR (DEL) | VAF 24/78 reads (31%) | called by pindel, varscan2
- CNNM1 | c.2340+9C>T | Intron (SNP) | VAF 126/348 reads (36%) | called by muse, varscan2
- DPY19L1 | c.*30C>A | 3'UTR (SNP) | VAF 108/227 reads (48%) | called by muse, varscan2
- DTNA | c.1662+2055_1662+2057del | Intron (DEL) | VAF 60/162 reads (37%) | called by pindel, varscan2
- LRIG3 | c.236+538_236+540del | Intron (DEL) | VAF 104/408 reads (25%) | catalogued as rs762896181; called by pindel, varscan2
- SGIP1 | c.-88C>T | 5'UTR (SNP) | VAF 70/201 reads (35%) | called by muse, varscan2
- TRIO | c.7632+15_7632+17del | Intron (DEL) | VAF 76/301 reads (25%) | called by pindel, varscan2
- USP29 | c.*32_*33del | 3'UTR (DEL) | VAF 17/59 reads (29%) | called by pindel, varscan2
- Y_RNA | chr8:38745414 C>A | 3'Flank (SNP) | VAF 96/548 reads (18%) | called by muse, varscan2
- ZFYVE21 | c.527-60G>T | Intron (SNP) | VAF 48/100 reads (48%) | called by muse, varscan2
